Somatic mutation profile of tumor specimen TCGA-DC-6160-01A (aliquot TCGA-DC-6160-01A-11D-1657-10) from TCGA case TCGA-DC-6160, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 68.4 years (24,990 days).
Specimen TCGA-DC-6160-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ffd7c52-21a8-46f2-86e5-82d86e18e098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-6160-10A (Blood Derived Normal), aliquot TCGA-DC-6160-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2cbf911-440e-43c1-9007-3c15b80e3816

The open-access MAF lists 86 somatic variants for this specimen: 68 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Nonsense Mutation 5, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 79/243 reads (33%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 47/170 reads (28%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 51/190 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 71/152 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA6 | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99446778; called by muse, mutect2, varscan2
- ABLIM3 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs138526744; called by muse, mutect2, varscan2
- ADGRE1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 165/592 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151096072, COSV51672989, COSV51674141; called by muse, mutect2, varscan2
- AHNAK2 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 318/941 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs749157355, COSV60920390; called by muse, mutect2, varscan2
- ATP4A | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762209271, COSV99382715; called by muse, mutect2, varscan2
- CD109 | c.1689G>T p.W563C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99753399, COSV99753861; called by muse, mutect2, varscan2
- CDH4 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100849111; called by muse, mutect2
- COL12A1 | c.5746G>A p.V1916I | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs778672810, COSV59398244; called by muse, mutect2, varscan2
- COL5A3 | c.3887C>T p.P1296L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs748724681, COSV53418449; called by muse, mutect2, varscan2
- CPEB3 | c.1085A>C p.E362A | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV99799779; called by muse, mutect2, varscan2
- CYP2A7 | c.495C>T p.G165= | Splice Region (SNP) | VAF 73/228 reads (32%) | catalogued as COSV99394197; called by muse, mutect2, varscan2
- DENND4A | c.2416G>T p.D806Y | Missense Mutation (SNP) | VAF 145/381 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV71266388; called by muse, mutect2, varscan2
- DNAH7 | c.8713A>G p.T2905A | Missense Mutation (SNP) | VAF 120/401 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs1412782905, COSV100415798; called by muse, mutect2, varscan2
- ENTPD4 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs757245710, COSV62270754; called by muse, mutect2, varscan2
- EPHB1 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs576710309, COSV101213156, COSV67655893; called by muse, mutect2, varscan2
- FAM13C | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53254285; called by muse, mutect2, varscan2
- FAM47A | c.2019_2020insC p.Y674Lfs*30 | Frame Shift Ins (INS) | VAF 135/302 reads (45%) | catalogued as COSV100649950; called by mutect2, pindel, varscan2
- IGFALS | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs908674331, COSV99236565; called by muse, mutect2, varscan2
- IL12RB2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs771299847, COSV52021440; called by muse, mutect2, varscan2
- IMPG2 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 62/460 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755792948, COSV99515769; called by muse, mutect2, varscan2
- KCNQ5 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs776285517, COSV59652775; called by muse, mutect2, varscan2
- KCNT1 | c.3002G>A p.R1001H (on ENST00000488444; = p.R1020H on NM_020822.3) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs373365707; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KLHL41 | c.1387A>G p.N463D | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.347); catalogued as COSV99500440; called by muse, mutect2, varscan2
- LIG4 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 136/494 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV100799944; called by muse, mutect2, varscan2
- LRIT2 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 77/209 reads (37%) | catalogued as rs139197166, COSV100258283; called by muse, mutect2, varscan2
- LRP1 | c.7369C>T p.R2457C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1374340095, COSV54519050; called by muse, mutect2, varscan2
- LRRC7 | c.328C>T p.R110* (on ENST00000651989 / NM_001370785.2; = p.R77* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/93 reads (43%) | catalogued as COSV50415481, COSV50652183; called by muse, mutect2, varscan2
- ME1 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs267601137, COSV63837600; called by muse, mutect2, varscan2
- MGA | c.6353A>T p.K2118I (on ENST00000219905 / NM_001164273.1; = p.K1909I on NM_001080541.2) | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV54957272; called by muse, mutect2, varscan2
- NBAS | c.6864A>T p.Q2288H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV99870322; called by muse, mutect2, varscan2
- NES | c.208del p.R70Afs*40 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV63961550; called by mutect2, varscan2
- OBSL1 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as rs778648112, COSV54707468; called by muse, mutect2, varscan2
- OR2J3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 21/614 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV101013582, COSV101013637; called by muse, mutect2
- PCDHB4 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV52024024; called by muse, mutect2
- PCGF2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1270907226; called by muse, mutect2, varscan2
- PKHD1 | c.10709C>A p.S3570* | Nonsense Mutation (SNP) | VAF 63/192 reads (33%) | catalogued as CM051187, COSV100944528, COSV64393361; called by muse, mutect2, varscan2
- PLEKHG4B | c.3715G>A p.V1239I (on ENST00000283426; = p.V1595I on NM_052909.5) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368497309; called by muse, mutect2, varscan2
- PLXNB3 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100737553; called by muse, mutect2, varscan2
- PPM1E | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100376355; called by muse, mutect2, varscan2
- PRG3 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs779423526, COSV54663411; called by muse, mutect2
- PSMB11 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs768517599, COSV57458972; called by muse, mutect2, varscan2
- RASGRF2 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.134); catalogued as rs376549001, COSV54133822; called by muse, mutect2, varscan2
- RGS22 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100693031, COSV62664027; called by muse, mutect2, varscan2
- RYR1 | c.6251G>A p.R2084Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs143681974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.3918G>A p.M1306I | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100771151; called by muse, mutect2, varscan2
- SBNO2 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755834135, COSV62321598; called by muse, mutect2, varscan2
- SDK2 | c.3064T>C p.S1022P | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV66190008; called by muse, mutect2, varscan2
- SEPTIN7 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 204/684 reads (30%) | catalogued as COSV100621831, COSV100621859, COSV63255040; called by muse, mutect2, varscan2
- SLX4 | c.5335C>T p.R1779W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs973283650, COSV53563687; called by muse, mutect2, varscan2
- SMCR8 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100329150; called by muse, mutect2
- SPTB | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV67631678; called by muse, mutect2, varscan2
- SYCP1 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101050840; called by muse, mutect2, varscan2
- TAF1L | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 166/532 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54258011; called by muse, mutect2, varscan2
- TMEM59L | c.316+1G>A p.X106_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99450319; called by muse, mutect2, varscan2
- TRPS1 | c.1712T>A p.L571H (on ENST00000220888 / NM_001330599.2; = p.L584H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.219); catalogued as COSV99631798, COSV99635491; called by muse, mutect2, varscan2
- WDR55 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs138378618; called by muse, mutect2, varscan2
- WNT3 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1303969028, COSV56645134, COSV56645539; called by muse, mutect2, varscan2
- ZNF324B | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764008537, COSV100351689; called by muse, mutect2, varscan2
- ZNF677 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs764153868, COSV61719732; called by muse, mutect2, varscan2
- ZNF99 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 137/500 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV68056041; called by muse, mutect2, varscan2
- HNRNPAB | c.980dup p.N327Kfs*2 (on ENST00000504898; = p.N280Kfs*2 on NM_004499.4) | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- OR13C3 | c.737dup p.S247Lfs*81 | Frame Shift Ins (INS) | VAF 42/120 reads (35%) | called by mutect2, varscan2
- PLA1A | c.723_748delinsA p.D241Efs*8 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by pindel, varscan2*
- TP53 | c.324_334del p.F109Lfs*36 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- ATP10A | c.819C>T p.D273= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs767281348, COSV100791344; called by muse, mutect2, varscan2
- COL4A5 | c.3651C>T p.G1217= | Silent (SNP) | VAF 56/89 reads (63%) | catalogued as COSV100088119, COSV60364375; called by muse, mutect2, varscan2
- DNAH5 | c.8397G>T p.R2799= | Silent (SNP) | VAF 98/348 reads (28%) | catalogued as COSV99450942; called by muse, mutect2, varscan2
- GABPA | c.1002C>T p.D334= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as rs761400758, COSV61397018; called by muse, mutect2, varscan2
- GON4L | c.291G>A p.V97= | Silent (SNP) | VAF 13/340 reads (4%) | called by muse, mutect2
- MARCHF10 | c.618G>A p.S206= | Silent (SNP) | VAF 253/761 reads (33%) | catalogued as rs780608983, COSV100248285, COSV60890354; called by muse, mutect2, varscan2
- MED25 | c.747C>T p.P249= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs111621037, COSV100457564, COSV57207942; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO1G | c.2682G>A p.Q894= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV99348818; called by muse, mutect2, varscan2
- NUAK1 | c.486C>T p.I162= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs267603280, COSV54606565; called by muse, mutect2, varscan2
- PXDNL | c.2436C>T p.H812= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1453645611, COSV62491694; called by muse, mutect2
- SLC7A4 | c.1347C>T p.H449= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs559055973, COSV60382554; called by muse, mutect2, varscan2
- SPN | c.942C>T p.A314= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV64070668; called by muse, mutect2, varscan2
- STAU2 | c.1338A>G p.Q446= (on ENST00000524300 / NM_001164380.2; = p.Q414= on NM_014393.2) | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as rs148124805; called by muse, mutect2, varscan2
- TH | c.378G>A p.A126= (on ENST00000381178 / NM_199292.3; = p.A95= on NM_000360.4) | Silent (SNP) | VAF 73/209 reads (35%) | catalogued as rs749856378, COSV100147109, COSV60767602; called by muse, mutect2, varscan2
- TULP2 | c.1353G>A p.S451= | Silent (SNP) | VAF 52/172 reads (30%) | catalogued as rs1568567318, COSV55478853; called by muse, mutect2, varscan2
- WT1 | c.1503G>A p.A501= | Silent (SNP) | VAF 95/267 reads (36%) | catalogued as rs202118284, COSV60065310; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF607 | c.264C>T p.S88= | Silent (SNP) | VAF 58/245 reads (24%) | catalogued as rs780296760, COSV62205656; called by muse, mutect2, varscan2
- KLK8 | c.71-99C>T | Intron (SNP) | VAF 33/95 reads (35%) | catalogued as rs111771104; called by muse, mutect2, varscan2
